Somatic mutation profile of tumor specimen c7aeb685-31b3-445e-8177-a3e729 (aliquot c7aeb685-31b3-445e-8177-a3e729_D6_1) from CPTAC case 01CO013, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen c7aeb685-31b3-445e-8177-a3e729: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18729d90-ed10-4b90-884f-6d064b470408.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen de434a02-cb27-4b7e-8013-7c289a (Blood Derived Normal), aliquot de434a02-cb27-4b7e-8013-7c289a_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae1329d8-73de-4143-83d9-6cf404439d27

The open-access MAF lists 90 somatic variants for this specimen: 67 protein-altering or splice-affecting, 11 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 11, Intron 6, Nonsense Mutation 5, 3'Flank 3, RNA 2, Frame Shift Del 1, Splice Region 1, In Frame Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 55/266 reads (21%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 147/356 reads (41%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 92/543 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751536987, COSV56996986; called by muse, mutect2, varscan2
- CSPG4 | c.5671G>A p.V1891M | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs771599626, COSV100414387, COSV57892372; called by muse, mutect2, varscan2
- DCAF8L2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs866230644, COSV70549990; called by muse, mutect2
- DLGAP2 | c.1158C>A p.S386R | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV101422498; called by muse, mutect2, varscan2
- DNAI2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 224/652 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs368225621, COSV56758767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM171A1 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs868766949; called by muse, mutect2, varscan2
- FCGBP | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs369676564; called by muse, mutect2
- FZD10 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs772807968; called by muse, mutect2, varscan2
- GK3P | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764206073, COSV56983100; called by muse, mutect2, varscan2
- HLCS | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 243/439 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs751093392, COSV60799033; called by muse, mutect2, varscan2
- HTT | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1359423552; called by muse, mutect2, varscan2
- IFIH1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99718685; called by muse, mutect2, varscan2
- KHK | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 124/780 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as rs549772974, COSV53150909; called by muse, mutect2, varscan2
- MAGEA3 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 158/318 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1556826506; called by muse, mutect2, varscan2
- MGAT4B | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs780334156; called by muse, mutect2, varscan2
- MYO16 | c.4661C>T p.A1554V | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs769347635; called by muse, mutect2, varscan2
- NIPBL | c.6908A>G p.N2303S | Missense Mutation (SNP) | VAF 90/467 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.115); catalogued as rs776353314; called by muse, mutect2, varscan2
- NNMT | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 116/426 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs137978367, COSV99037328; called by muse, mutect2, varscan2
- OR2AK2 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63564981; called by muse, mutect2, varscan2
- OR56A5 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs778078804, COSV60827030; called by muse, mutect2, varscan2
- PCDHA5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 67/354 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1393571238, COSV65349067; called by muse, mutect2, varscan2
- PNLIPRP1 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62610614, COSV62611603; called by muse, mutect2, varscan2
- POLR3A | c.3296G>A p.R1099H | Missense Mutation (SNP) | VAF 62/417 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1225262284; called by muse, mutect2, varscan2
- PTPRB | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.013); catalogued as rs925084256, COSV99317457; called by muse, mutect2, varscan2
- R3HDM2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV61284959; called by muse, mutect2, varscan2
- RASGEF1A | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs760968520; called by muse, mutect2
- SMAD4 | c.1140G>T p.R380S | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61693378, COSV61697006; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 99/355 reads (28%) | PolyPhen probably damaging (0.959); catalogued as rs763867212, COSV59561902; called by muse, mutect2, varscan2
- SYNE1 | c.14902G>A p.A4968T (on ENST00000367255 / NM_182961.4; = p.A4897T on NM_033071.3) | Missense Mutation (SNP) | VAF 124/448 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs745978878, COSV54924424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7L2 | c.751G>T p.G251* (on ENST00000355995 / NM_001367943.1; = p.G228* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 43/131 reads (33%) | catalogued as COSV53344427; called by muse, mutect2, varscan2
- TEKT4 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 46/798 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.623); catalogued as rs782762953; called by muse, mutect2
- TIAM2 | c.1176G>T p.R392S | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100018130; called by muse, mutect2, varscan2
- TRANK1 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 150/473 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs201862568; called by muse, mutect2, varscan2
- TRIM64C | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 202/683 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs546301976; called by muse, mutect2, varscan2
- TRMT1 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.553); catalogued as rs554080215, COSV99317097; called by muse, mutect2, varscan2
- ZZEF1 | c.8500G>A p.V2834M | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778892306; called by muse, mutect2, varscan2
- ABHD14B | c.-28-5C>T | Splice Region (SNP) | VAF 44/175 reads (25%) | called by muse, mutect2, varscan2
- ADM | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ANKFN1 | c.2065G>T p.A689S | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD109 | c.834A>C p.K278N | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CHD3 | c.3345G>T p.R1115S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- COA7 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB118 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 90/484 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DLEC1 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- EP400 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 84/282 reads (30%) | called by mutect2, varscan2
- GLRA3 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 60/200 reads (30%) | called by muse, mutect2, varscan2
- GPR27 | c.898T>C p.Y300H | Missense Mutation (SNP) | VAF 162/568 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH1 | c.701T>C p.F234S | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ITPR1 | c.7035_7036del p.V2348Rfs*17 (on ENST00000354582; = p.V2293Rfs*17 on NM_002222.7) | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | called by pindel, varscan2
- LCE2B | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAP4K1 | c.1670-1G>A p.X557_splice | Splice Site (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- MN1 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH2 | c.2083G>T p.V695F | Missense Mutation (SNP) | VAF 217/505 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- NDUFB6 | c.310A>T p.I104L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NTM | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRPF40A | c.2351A>T p.E784V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RASIP1 | c.2502G>A p.M834I | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPTOR | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTB | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 11/283 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2
- STING1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 105/340 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TP53 | c.1170_1172del p.D391del | In Frame Del (DEL) | VAF 77/313 reads (25%) | called by mutect2, pindel*, varscan2*
- TRPM3 | c.3380C>A p.S1127Y (on ENST00000357533 / NM_001366142.2; = p.S982Y on NM_020952.6) | Missense Mutation (SNP) | VAF 134/488 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTC6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2
- ZNF700 | c.1529G>T p.C510F | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATCAY | c.435C>T p.D145= | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as rs547532756; called by muse, mutect2, varscan2
- CATSPER1 | c.423C>T p.S141= | Silent (SNP) | VAF 90/374 reads (24%) | catalogued as COSV100376146; called by mutect2, varscan2
- CDH23 | c.6960C>T p.A2320= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as rs1272670975; called by muse, mutect2, varscan2
- HELZ | c.3498C>T p.P1166= | Silent (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- KCNG2 | c.159C>T p.D53= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- MTRF1 | c.963C>T p.A321= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as rs147031181, COSV101067571; called by muse, mutect2, varscan2
- PER1 | c.2343C>T p.A781= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs537123990, COSV57921770; called by muse, mutect2, varscan2
- SLC37A2 | c.135C>T p.I45= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as rs571262164, COSV100016892, COSV53523938; called by muse, mutect2, varscan2
- SUCO | c.1044A>G p.K348= | Silent (SNP) | VAF 36/166 reads (22%) | called by muse, mutect2, varscan2
- THBS2 | c.339C>T p.F113= | Silent (SNP) | VAF 113/500 reads (23%) | catalogued as rs1411492488, COSV64677168; called by muse, mutect2, varscan2
- TRPM2 | c.885C>T p.Y295= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs368732556; called by muse, mutect2, varscan2
- AC244394.2 | n.1570G>T | RNA (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- C4A | chr6:32006718 C>T | 3'Flank (SNP) | VAF 64/1116 reads (6%) | called by muse, mutect2
- COL5A1 | c.109+7288del | Intron (DEL) | VAF 32/91 reads (35%) | catalogued as rs1013171129; called by mutect2, varscan2
- DBN1 | c.331-29G>A | Intron (SNP) | VAF 153/482 reads (32%) | catalogued as rs532650723; called by muse, mutect2, varscan2
- DHX30 | c.125-2128T>A | Intron (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- DLG1 | c.483+10829G>A | Intron (SNP) | VAF 77/294 reads (26%) | catalogued as rs1362164023; called by muse, mutect2, varscan2
- FAM183BP | n.355C>T | RNA (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- GATA4 | chr8:11761978 C>T | 3'Flank (SNP) | VAF 74/213 reads (35%) | catalogued as rs865992526; called by muse, varscan2
- HAUS7 | chrX:153470812 del GGGGCGGGGCGGACACCGGGAAGGAGGCGGGGCGGACACCGGGAAA | 5'Flank (DEL) | VAF 5/58 reads (9%) | catalogued as rs1556985112; called by mutect2, varscan2*
- HOXA7 | chr7:27153038 G>A | 3'Flank (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- NPIPA1 | c.63+789G>A | Intron (SNP) | VAF 53/469 reads (11%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3232G>A | Intron (SNP) | VAF 29/100 reads (29%) | catalogued as rs1366388810; called by muse, mutect2, varscan2
